Somatic mutation profile of tumor specimen TCGA-5B-A90C-01A (aliquot TCGA-5B-A90C-01A-11D-A37N-09) from TCGA case TCGA-5B-A90C, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 69.9 years (25,518 days).
Specimen TCGA-5B-A90C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6eda372c-812a-40cb-93eb-d04fbcd6e36e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5B-A90C-10A (Blood Derived Normal), aliquot TCGA-5B-A90C-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e43a4d87-20f5-486b-92db-a7421a09943f

The open-access MAF lists 56 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 12, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 28/48 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 36/43 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.166-2A>C p.X56_splice | Splice Site (SNP) | VAF 10/33 reads (30%) | catalogued as COSV99700285; called by muse, mutect2, varscan2
- ARHGAP11A | c.234C>A p.D78E | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761417404, COSV64381718; called by muse, mutect2, varscan2
- BRD2 | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100875841; called by muse, mutect2, varscan2
- CACNA1S | c.4601G>A p.R1534Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs891244994, COSV62938443; ClinVar: uncertain significance; called by muse, mutect2
- CDH19 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs751599227, COSV100052386; called by muse, mutect2, varscan2
- CNTN3 | c.1999C>A p.P667T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs754320954, COSV99726152; called by muse, mutect2, varscan2
- DCST2 | c.1998G>T p.W666C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99792268; called by muse, mutect2, varscan2
- EXD3 | c.1754C>A p.P585H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.785); catalogued as COSV100573968; called by muse, mutect2, varscan2
- GMNN | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as rs757212388, COSV100017791; called by muse, mutect2, varscan2
- H2AC12 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.068); catalogued as rs370014824; called by muse, mutect2, varscan2
- INTS3 | c.1876T>C p.F626L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (1); PolyPhen probably damaging (0.916); catalogued as COSV100016524; called by muse, mutect2, varscan2
- IRS4 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.982); catalogued as rs770826786, COSV64535307; called by muse, mutect2, varscan2
- KMO | c.1237C>G p.Q413E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100087891; called by muse, mutect2, varscan2
- KRT6A | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs762168782, COSV100417243; called by muse, mutect2, varscan2
- NANOG | c.845G>T p.R282M | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99981747; called by muse, mutect2, varscan2
- NBEA | c.7082G>A p.R2361H | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs780216276, COSV59763487, COSV59794440; called by muse, mutect2, varscan2
- PCDHGA4 | c.2119G>A p.G707S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.059); catalogued as COSV54061834, COSV99547317; called by muse, mutect2, varscan2
- PCSK5 | c.3997T>G p.C1333G | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV101377716; called by muse, mutect2, varscan2
- PIP4K2C | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV100723996; called by muse, mutect2, varscan2
- PKM | c.604T>C p.S202P | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.294); catalogued as COSV100065258; called by muse, mutect2, varscan2
- RNF19A | c.1169T>A p.I390N | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100348132; called by muse, mutect2, varscan2
- SCN3A | c.1388C>A p.A463E | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV51808422, COSV99328585; called by muse, mutect2, varscan2
- SERGEF | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201145367, COSV99787865; called by muse, mutect2, varscan2
- SERGEF | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99787866; called by muse, mutect2, varscan2
- SH3PXD2B | c.2259G>T p.Q753H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100288554, COSV61129457; called by muse, mutect2
- SPNS1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.734); catalogued as rs749827751, COSV57956065; called by muse, mutect2, varscan2
- SPTBN5 | c.10657C>T p.P3553S | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs1191311661, COSV100312226; called by muse, mutect2, varscan2
- SRRM4 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as rs763862350, COSV57413809; called by muse, mutect2, varscan2
- SYNPO2 | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.51); catalogued as rs759797608, COSV61116874; called by muse, mutect2, varscan2
- TANC2 | c.2600G>A p.R867Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1244021783, COSV67339967; called by muse, mutect2, varscan2
- THOC2 | c.270A>G p.I90M | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV99834204; called by muse, mutect2, varscan2
- TRAPPC5 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs201747018, COSV100365448; called by muse, mutect2, varscan2
- WDR17 | c.3455C>T p.T1152M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs749386548, COSV99708315; called by muse, mutect2, varscan2
- XPR1 | c.935C>A p.S312Y | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100851524; called by muse, mutect2, varscan2
- ZBTB12 | c.443G>T p.S148I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as COSV100977047; called by muse, mutect2, varscan2
- CHD7 | c.2960_2967del p.R987Hfs*5 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- CLPX | c.403G>T p.V135F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- GPM6A | c.280_288del p.V94_G96del | In Frame Del (DEL) | VAF 7/11 reads (64%) | called by mutect2, varscan2
- MLF1 | c.333_345del p.M111Ifs*2 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel, varscan2
- RHBDF1 | c.2270del p.F757Sfs*170 | Frame Shift Del (DEL) | VAF 25/40 reads (63%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1852C>T p.Q618* | Nonsense Mutation (SNP) | VAF 39/314 reads (12%) | called by muse, mutect2, varscan2
- CMSS1 | c.543C>T p.D181= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs566817716, COSV70437344; called by muse, mutect2
- CSPG4 | c.2697G>A p.A899= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs144209551; called by muse, mutect2, varscan2
- FLG2 | c.5589A>G p.G1863= | Silent (SNP) | VAF 50/91 reads (55%) | catalogued as COSV66169195; called by muse, mutect2, varscan2
- FN1 | c.4425G>A p.V1475= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100117091; called by muse, mutect2, varscan2
- GAD2 | c.1038C>A p.P346= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV52160644; called by muse, mutect2, varscan2
- KCNK10 | c.1404C>T p.D468= | Silent (SNP) | VAF 36/49 reads (73%) | catalogued as rs368641869; called by muse, mutect2, varscan2
- MYT1L | c.576C>T p.D192= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as rs370624330, COSV67734896; called by muse, mutect2, varscan2
- NCOR2 | c.3216C>A p.P1072= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100657907, COSV62304400; called by mutect2, varscan2
- PLXNA2 | c.2574T>A p.P858= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV100885998; called by muse, mutect2, varscan2
- RND1 | c.678C>G p.A226= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV100552238; called by muse, mutect2, varscan2
- SLC1A5 | c.738G>T p.R246= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV101314827; called by muse, mutect2, varscan2
- UBA1 | c.2073G>C p.V691= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV100256100; called by muse, mutect2, varscan2
- GABRG2 | c.1248+273G>T | Intron (SNP) | VAF 13/35 reads (37%) | catalogued as rs1489198196; called by muse, mutect2, varscan2
